Somatic mutation profile of cancer-model specimen HCM-BROD-0489-C15-85M (3D Organoid, passage 4; aliquot HCM-BROD-0489-C15-85M-01D-A83U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0489-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 63.9 years (23,343 days).
Specimen HCM-BROD-0489-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07ef30c0-87c0-47b6-9a49-8976d4e6cb45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0489-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0489-C15-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e235f60-704e-4b5e-8d1e-b343b6a580b2

The open-access MAF lists 189 somatic variants for this specimen: 133 protein-altering or splice-affecting, 49 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 49, Nonsense Mutation 7, Intron 5, Splice Region 3, Frame Shift Del 3, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADVL | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 196/225 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398123083, CM990103; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SRD5A2 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 768/1531 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782032018, CM083162, CM920630; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 318/377 reads (84%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 24/464 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADGRV1 | c.18610G>A p.G6204S | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745735875; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP13A3 | c.1420A>G p.K474E | Missense Mutation (SNP) | VAF 252/430 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV99756447; called by muse, mutect2, varscan2
- BRAP | c.316C>G p.H106D | Missense Mutation (SNP) | VAF 92/339 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100554104; called by muse, mutect2, varscan2
- CALCOCO1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 128/450 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1030520322, COSV100017258; called by muse, mutect2, varscan2
- CDKN1B | c.275del p.P92Rfs*27 | Frame Shift Del (DEL) | VAF 538/1043 reads (52%) | catalogued as COSV57430859; called by mutect2, pindel, varscan2
- COQ9 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 397/397 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs761979107; ClinVar: uncertain significance; called by muse, varscan2
- CUL3 | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 228/228 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1206525768, COSV52364995; called by muse, mutect2, varscan2
- CYP2S1 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 495/810 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs773132133, COSV59506131; called by muse, mutect2, varscan2
- DUOXA1 | c.147G>A p.T49= | Splice Region (SNP) | VAF 171/171 reads (100%) | catalogued as rs777728957; called by muse, mutect2, varscan2
- ERFL | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 144/408 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61529481; called by muse, mutect2, varscan2
- ETV3L | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 493/940 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs1003386769, COSV101485623; called by muse, mutect2, varscan2
- FANCD2 | c.3776A>T p.Q1259L | Missense Mutation (SNP) | VAF 194/339 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs1486214768; called by mutect2, varscan2
- GABBR2 | c.2395C>T p.R799* | Nonsense Mutation (SNP) | VAF 179/546 reads (33%) | catalogued as rs1385823880; called by muse, mutect2, varscan2
- GARRE1 | c.2153C>A p.A718E | Missense Mutation (SNP) | VAF 513/803 reads (64%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.112); catalogued as rs1191158315; called by muse, mutect2, varscan2
- GLP2R | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 213/252 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs905339283, COSV52321936; called by muse, mutect2, varscan2
- GPATCH2L | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776356960, COSV55046856; called by muse, mutect2, varscan2
- GPATCH8 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 23/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100132393; called by muse, mutect2
- GREM2 | c.68A>G p.K23R | Missense Mutation (SNP) | VAF 526/980 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV58953260; called by muse, mutect2, varscan2
- KAT6A | c.4715C>T p.T1572M | Missense Mutation (SNP) | VAF 202/645 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749654604, COSV55904044; called by muse, mutect2, varscan2
- KDM2A | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 352/650 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs777607633, COSV58189005, COSV58189543; called by muse, varscan2
- KIF2B | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 56/740 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs753464095, COSV52127156; called by muse, mutect2
- KIFC1 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 419/419 reads (100%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs772206166, COSV65728644, COSV65729169; called by muse, mutect2, varscan2
- LACRT | c.386A>C p.K129T | Missense Mutation (SNP) | VAF 199/342 reads (58%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.782); catalogued as COSV57688176; called by muse, mutect2, varscan2
- LRP1 | c.4738G>A p.E1580K | Missense Mutation (SNP) | VAF 144/396 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV99675754; called by muse, mutect2, varscan2
- MED27 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 98/310 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1430956704, COSV52605948; called by muse, mutect2, varscan2
- MYO1B | c.135C>T p.Y45= | Splice Region (SNP) | VAF 212/212 reads (100%) | catalogued as rs751458267; called by muse, varscan2
- NUP205 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 308/308 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257811759; called by muse, mutect2, varscan2
- OR4C5 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 165/165 reads (100%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.021); catalogued as rs78030134; called by muse, mutect2, varscan2
- OR5L2 | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 151/445 reads (34%) | catalogued as COSV65724280; called by muse, mutect2, varscan2
- PCDHGB6 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 340/340 reads (100%) | SIFT tolerated (0.9); PolyPhen benign (0.044); catalogued as COSV53992828; called by muse, mutect2, varscan2
- PDPN | c.51G>C p.W17C (on ENST00000621990; = p.W93C on NM_006474.4) | Missense Mutation (SNP) | VAF 640/640 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557531573; called by mutect2, varscan2
- PLXNA1 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 584/943 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1199026244, COSV99302394; called by muse, mutect2, varscan2
- PML | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 494/496 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs1251227417, COSV51443576; called by muse, mutect2, varscan2
- PROS1 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 157/504 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM022239; called by muse, mutect2, varscan2
- REC8 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 161/353 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs377303811; called by muse, mutect2, varscan2
- SCN1A | c.5620C>T p.R1874W (on ENST00000303395 / NM_001202435.3; = p.R1863W on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 254/254 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796053043, COSV57670031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCRIB | c.3754G>A p.E1252K | Missense Mutation (SNP) | VAF 357/936 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs769393665, COSV57590578; called by muse, varscan2
- SIGLEC10 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 114/445 reads (26%) | SIFT tolerated (0.96); PolyPhen benign (0.014); catalogued as rs201868126; called by muse, varscan2
- SLC6A19 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 190/522 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs200657233, COSV58673018; called by muse, mutect2, varscan2
- SP8 | c.971G>A p.R324H (on ENST00000361443 / NM_198956.4; = p.R342H on NM_182700.6) | Missense Mutation (SNP) | VAF 86/865 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as rs1324645918; called by muse, mutect2
- SPATA31E1 | c.4030C>T p.R1344C | Missense Mutation (SNP) | VAF 238/818 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs777477102; called by muse, mutect2
- SYNDIG1 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 480/748 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs781070155; called by muse, mutect2, varscan2
- SYNPO2 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 175/355 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61111415; called by muse, mutect2, varscan2
- TMF1 | c.2710C>G p.Q904E | Missense Mutation (SNP) | VAF 78/78 reads (100%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.753); catalogued as rs970008570; called by muse, mutect2, varscan2
- TRIM67 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 126/383 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs1311342154, COSV64160830; called by muse, mutect2, varscan2
- UBA7 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 198/384 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV61091300; called by muse, mutect2, varscan2
- WDR4 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 299/299 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs771861414; called by muse, mutect2, varscan2
- ZC3H11B | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 242/263 reads (92%) | SIFT tolerated (0.1); PolyPhen benign (0.221); catalogued as rs1412126381, COSV65844923; called by muse, mutect2, varscan2
- ZFAT | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 398/686 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64749539; called by muse, mutect2, varscan2
- ZNF568 | c.1255G>T p.V419L | Missense Mutation (SNP) | VAF 306/485 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV61741245; called by muse, mutect2, varscan2
- ZNF688 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 22/626 reads (4%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.69); catalogued as COSV56300618; called by muse, mutect2
- AFAP1L1 | c.1347G>C p.K449N | Missense Mutation (SNP) | VAF 497/497 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- AFF2 | c.3081_3092del p.S1028_T1031del | In Frame Del (DEL) | VAF 329/363 reads (91%) | called by mutect2, varscan2
- ANXA9 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 342/658 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ARHGEF26 | c.2206T>A p.S736T | Missense Mutation (SNP) | VAF 352/568 reads (62%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- BAZ1B | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 32/404 reads (8%) | called by muse, mutect2
- C8orf34 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 145/379 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CEMIP2 | c.1078T>C p.S360P | Missense Mutation (SNP) | VAF 202/202 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CLEC11A | c.25G>C p.A9P | Missense Mutation (SNP) | VAF 192/736 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- CNGA4 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 203/362 reads (56%) | called by muse, mutect2, varscan2
- DGKD | c.2926G>A p.E976K (on ENST00000264057 / NM_152879.3; = p.E932K on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 401/402 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- DGKQ | c.2226G>T p.M742I | Missense Mutation (SNP) | VAF 91/245 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- EFHB | c.658C>G p.Q220E | Missense Mutation (SNP) | VAF 158/557 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELF5 | c.559G>A p.E187K (on ENST00000312319 / NM_198381.2; = p.E177K on NM_001422.4) | Missense Mutation (SNP) | VAF 193/193 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- EMILIN1 | c.1960T>G p.F654V | Missense Mutation (SNP) | VAF 426/859 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EYA1 | c.33T>G p.S11= | Splice Region (SNP) | VAF 104/300 reads (35%) | called by muse, mutect2, varscan2
- FARS2 | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 249/250 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- FGF13 | c.643T>G p.F215V | Missense Mutation (SNP) | VAF 249/249 reads (100%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FLG | c.5916C>A p.D1972E | Missense Mutation (SNP) | VAF 243/535 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FNDC3B | c.3193_3196del p.L1065Kfs*15 | Frame Shift Del (DEL) | VAF 65/238 reads (27%) | called by mutect2, pindel, varscan2
- FRMPD3 | c.2328G>C p.E776D | Missense Mutation (SNP) | VAF 390/391 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FUT4 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 367/1262 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT13 | c.1507C>A p.Q503K | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPRASP1 | c.2762C>T p.A921V | Missense Mutation (SNP) | VAF 189/418 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- GSK3A | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 38/924 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.025); called by muse, mutect2
- H2BC13 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 99/248 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- HEATR5B | c.6004C>G p.L2002V | Missense Mutation (SNP) | VAF 303/629 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- INTS11 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 553/553 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- IPO4 | c.2035G>T p.A679S | Missense Mutation (SNP) | VAF 141/304 reads (46%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- KBTBD3 | c.791G>A p.S264N | Missense Mutation (SNP) | VAF 323/554 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KCNT1 | c.1188G>T p.Q396H (on ENST00000488444; = p.Q415H on NM_020822.3) | Missense Mutation (SNP) | VAF 192/547 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- KIAA1210 | c.2636C>A p.A879D | Missense Mutation (SNP) | VAF 421/423 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KRTAP1-5 | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 608/669 reads (91%) | SIFT tolerated (0.88); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MALRD1 | c.6343T>A p.F2115I | Missense Mutation (SNP) | VAF 202/370 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); called by muse, varscan2
- MARCHF4 | c.415T>G p.F139V | Missense Mutation (SNP) | VAF 517/517 reads (100%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- MORC3 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 115/115 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- NEK10 | c.1253C>A p.A418E | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NOVA1 | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 154/273 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NPHS1 | c.3167G>A p.G1056E | Missense Mutation (SNP) | VAF 167/504 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NT5E | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 117/257 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NTRK3 | c.2486A>C p.K829T (on ENST00000360948 / NM_001012338.2; = p.K815T on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 412/412 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR10H2 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 262/262 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL1A | c.579A>C p.L193F | Missense Mutation (SNP) | VAF 118/303 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PDE3A | c.1202T>G p.L401R | Missense Mutation (SNP) | VAF 280/504 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2
- PGBD2 | c.1680G>T p.R560S | Missense Mutation (SNP) | VAF 30/885 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2
- PLEC | c.4885G>T p.A1629S (on ENST00000322810 / NM_201380.4; = p.A1519S on NM_000445.5) | Missense Mutation (SNP) | VAF 342/1359 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- POTEJ | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 129/191 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PPP1R12A | c.2014C>A p.P672T | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRR29 | c.336C>A p.Y112* | Nonsense Mutation (SNP) | VAF 696/764 reads (91%) | called by muse, mutect2, varscan2
- RAB27A | c.393T>A p.C131* | Nonsense Mutation (SNP) | VAF 67/159 reads (42%) | called by muse, mutect2, varscan2
- RAB41 | c.215C>T p.T72I (on ENST00000374473 / NM_001363807.1; = p.T71I on NM_001032726.3) | Missense Mutation (SNP) | VAF 151/151 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- RCC1 | c.653A>G p.Q218R | Missense Mutation (SNP) | VAF 168/168 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUFY3 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 130/262 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUSC2 | c.2287A>G p.R763G | Missense Mutation (SNP) | VAF 248/477 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPIND1 | c.273C>G p.D91E | Missense Mutation (SNP) | VAF 443/443 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SETD2 | c.2954G>A p.G985E | Missense Mutation (SNP) | VAF 237/237 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC30A8 | c.758T>A p.F253Y | Missense Mutation (SNP) | VAF 138/331 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC30A8 | c.759C>A p.F253L | Missense Mutation (SNP) | VAF 137/329 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SLCO1B1 | c.1320G>A p.M440I | Missense Mutation (SNP) | VAF 128/205 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SOAT2 | c.152A>G p.Q51R | Missense Mutation (SNP) | VAF 294/484 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPTAN1 | c.1473G>C p.L491F | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- SV2B | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 325/325 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SVOP | c.1628A>C p.N543T | Missense Mutation (SNP) | VAF 141/483 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE3 | c.2243T>G p.L748R | Missense Mutation (SNP) | VAF 147/322 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TEX36 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 130/512 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TLN2 | c.259_260del p.Q87Efs*19 | Frame Shift Del (DEL) | VAF 212/290 reads (73%) | called by mutect2, pindel, varscan2
- TMPRSS15 | c.2485G>A p.G829R | Missense Mutation (SNP) | VAF 209/209 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- TMPRSS15 | c.2272T>A p.L758I | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- UBA2 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 188/677 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBA2 | c.354C>G p.N118K | Missense Mutation (SNP) | VAF 117/233 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBA6 | c.2908G>C p.D970H | Missense Mutation (SNP) | VAF 120/120 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- USP17L10 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 48/639 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2
- WDR72 | c.967C>A p.P323T | Missense Mutation (SNP) | VAF 184/184 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- WNT10A | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 806/806 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, varscan2
- XIAP | c.1024A>G p.I342V | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT tolerated (0.91); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZIM3 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 102/343 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF195 | c.1370G>A p.R457K (on ENST00000399602 / NM_001130520.3; = p.R385K on NM_007152.5) | Missense Mutation (SNP) | VAF 159/278 reads (57%) | SIFT tolerated (1); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ZNF667 | c.1485A>C p.E495D | Missense Mutation (SNP) | VAF 297/512 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- ZNF729 | c.1499T>C p.F500S | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAMTS7 | c.5055C>T p.R1685= | Silent (SNP) | VAF 376/377 reads (100%) | called by muse, mutect2, varscan2
- ADAMTSL4 | c.357G>A p.R119= | Silent (SNP) | VAF 309/778 reads (40%) | catalogued as COSV99647684; called by muse, mutect2, varscan2
- ADARB2 | c.1629C>T p.G543= | Silent (SNP) | VAF 147/777 reads (19%) | catalogued as rs371274182; called by muse, mutect2, varscan2
- ADCY8 | c.1896C>T p.I632= | Silent (SNP) | VAF 142/390 reads (36%) | catalogued as rs750606350, COSV53905624; called by muse, mutect2, varscan2
- ADGRV1 | c.18549G>T p.T6183= | Silent (SNP) | VAF 314/314 reads (100%) | catalogued as rs192571483; called by muse, mutect2, varscan2
- ANKRD60 | c.1023G>A p.T341= | Silent (SNP) | VAF 195/195 reads (100%) | catalogued as rs1472540031; called by muse, mutect2, varscan2
- ARHGEF33 | c.1440C>A p.P480= | Silent (SNP) | VAF 194/812 reads (24%) | called by muse, mutect2, varscan2
- CAMK1D | c.687C>T p.L229= | Silent (SNP) | VAF 217/403 reads (54%) | called by muse, mutect2, varscan2
- CXorf21 | c.555A>T p.S185= | Silent (SNP) | VAF 195/396 reads (49%) | called by muse, mutect2, varscan2
- DHX35 | c.1023C>T p.A341= | Silent (SNP) | VAF 62/202 reads (31%) | called by muse, mutect2, varscan2
- DLGAP2 | c.816C>A p.A272= | Silent (SNP) | VAF 708/708 reads (100%) | called by muse, mutect2, varscan2
- ELMOD2 | c.435C>T p.N145= | Silent (SNP) | VAF 92/230 reads (40%) | catalogued as rs751771607; called by muse, varscan2
- ENPP7 | c.459T>G p.A153= | Silent (SNP) | VAF 429/469 reads (91%) | called by muse, mutect2, varscan2
- FAM20C | c.309G>A p.S103= | Silent (SNP) | VAF 483/545 reads (89%) | called by muse, mutect2, varscan2
- FAM86B1 | c.513C>T p.G171= | Silent (SNP) | VAF 132/734 reads (18%) | catalogued as rs1226885519; called by muse, mutect2, varscan2
- FAM86B2 | c.615C>T p.G205= | Silent (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- FLG2 | c.4269C>A p.G1423= | Silent (SNP) | VAF 235/593 reads (40%) | catalogued as rs144473873, COSV66170960; called by muse, mutect2, varscan2
- GFUS | c.861C>T p.S287= | Silent (SNP) | VAF 154/734 reads (21%) | called by muse, mutect2, varscan2
- GIT1 | c.162C>T p.S54= | Silent (SNP) | VAF 43/568 reads (8%) | catalogued as rs778573748; called by muse, mutect2
- GJC2 | c.309C>T p.A103= | Silent (SNP) | VAF 57/299 reads (19%) | called by muse, mutect2, varscan2
- GPLD1 | c.1051A>C p.R351= | Silent (SNP) | VAF 315/316 reads (100%) | called by muse, mutect2, varscan2
- GSC | c.222C>T p.S74= | Silent (SNP) | VAF 375/721 reads (52%) | catalogued as rs1187728766; called by muse, mutect2, varscan2
- H1-7 | c.402C>T p.R134= | Silent (SNP) | VAF 667/1015 reads (66%) | called by muse, mutect2, varscan2
- HAS2 | c.1658G>A p.*553= | Silent (SNP) | VAF 88/225 reads (39%) | called by muse, mutect2, varscan2
- IMPG1 | c.2220C>T p.L740= | Silent (SNP) | VAF 211/211 reads (100%) | catalogued as rs1357665042, COSV100774832; called by muse, mutect2, varscan2
- KCNB2 | c.2151G>A p.V717= | Silent (SNP) | VAF 49/848 reads (6%) | called by muse, mutect2
- LAMA5 | c.8460C>T p.I2820= | Silent (SNP) | VAF 159/395 reads (40%) | catalogued as rs377471638; called by muse, mutect2, varscan2
- LLCFC1 | c.324G>A p.S108= (on ENST00000458732; = p.S77= on NM_178829.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 485/485 reads (100%) | catalogued as rs767114431, COSV62338099; called by muse, mutect2, varscan2
- NACA | c.627G>A p.A209= | Silent (SNP) | VAF 132/456 reads (29%) | catalogued as rs760650214; called by muse, mutect2, varscan2
- PALD1 | c.735C>T p.D245= | Silent (SNP) | VAF 389/795 reads (49%) | catalogued as rs148437569; called by muse, mutect2, varscan2
- PDCD6 | c.126G>A p.V42= | Silent (SNP) | VAF 275/452 reads (61%) | called by muse, mutect2, varscan2
- PGAM5 | c.453G>A p.T151= | Silent (SNP) | VAF 148/508 reads (29%) | catalogued as rs547560937, COSV58201709; called by muse, mutect2, varscan2
- PMCH | c.286C>T p.L96= | Silent (SNP) | VAF 186/286 reads (65%) | called by muse, mutect2, varscan2
- PRKD1 | c.27G>A p.P9= | Silent (SNP) | VAF 171/347 reads (49%) | called by muse, mutect2, varscan2
- PVRIG | c.618G>A p.P206= | Silent (SNP) | VAF 413/474 reads (87%) | catalogued as rs768595596; called by muse, mutect2, varscan2
- ROBO1 | c.1710A>G p.T570= | Silent (SNP) | VAF 289/289 reads (100%) | catalogued as COSV101459128; called by muse, mutect2, varscan2
- ROCK2 | c.495G>T p.L165= | Silent (SNP) | VAF 176/376 reads (47%) | called by muse, mutect2, varscan2
- SCRIB | c.2745C>A p.V915= | Silent (SNP) | VAF 60/952 reads (6%) | called by muse, mutect2
- SH3RF1 | c.2115A>G p.A705= | Silent (SNP) | VAF 189/189 reads (100%) | called by muse, mutect2, varscan2
- STARD10 | c.174T>A p.A58= | Silent (SNP) | VAF 381/650 reads (59%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2787C>T p.P929= | Silent (SNP) | VAF 283/283 reads (100%) | catalogued as COSV62282260; called by muse, mutect2, varscan2
- TECTB | c.954C>T p.H318= | Silent (SNP) | VAF 161/654 reads (25%) | catalogued as COSV65596693; called by muse, mutect2, varscan2
- TEKT4 | c.858C>T p.D286= | Silent (SNP) | VAF 612/612 reads (100%) | catalogued as rs782775406; called by muse, mutect2, varscan2
- TGFBR3L | c.903G>A p.P301= | Silent (SNP) | VAF 506/506 reads (100%) | catalogued as COSV55603888; called by muse, mutect2, varscan2
- TPCN1 | c.21C>T p.D7= | Silent (SNP) | VAF 155/542 reads (29%) | catalogued as rs752402361; called by muse, mutect2, varscan2
- TTN | c.6489C>T p.H2163= (on ENST00000591111; = p.H2117= on NM_003319.4) | Silent (SNP) | VAF 275/277 reads (99%) | catalogued as rs762045402, COSV59945091; ClinVar: likely benign; called by muse, mutect2, varscan2
- TULP4 | c.336C>T p.Y112= | Silent (SNP) | VAF 279/280 reads (100%) | catalogued as rs747287567, COSV65581727; called by muse, mutect2, varscan2
- VHL | c.105C>G p.A35= | Silent (SNP) | VAF 497/1388 reads (36%) | catalogued as rs1310829877, COSV56559242; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- WDR81 | c.381C>T p.D127= | Silent (SNP) | VAF 92/894 reads (10%) | catalogued as rs1238743220; called by muse, mutect2
- AC244258.1 | n.303C>T | RNA (SNP) | VAF 145/150 reads (97%) | called by muse, mutect2, varscan2
- AGAP12P | n.1429C>T | RNA (SNP) | VAF 471/517 reads (91%) | catalogued as rs782244870; called by mutect2, varscan2
- AP000790.1 | n.379-8331G>C | Intron (SNP) | VAF 78/230 reads (34%) | called by muse, mutect2, varscan2
- FHOD3 | c.1197-5303C>A | Intron (SNP) | VAF 220/221 reads (100%) | called by muse, mutect2, varscan2
- KCNMA1 | c.378+868G>A | Intron (SNP) | VAF 163/630 reads (26%) | catalogued as rs879255370, COSV54236428; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCN10 | c.258-279C>T | Intron (SNP) | VAF 267/446 reads (60%) | called by muse, mutect2, varscan2
- PRRG3 | c.168+102C>A | Intron (SNP) | VAF 318/319 reads (100%) | called by muse, mutect2, varscan2
